Somatic mutation profile of tumor specimen TARGET-20-PARFWM-09A (aliquot TARGET-20-PARFWM-09A-01D) from TARGET case TARGET-20-PARFWM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.2 years (4,441 days).
Specimen TARGET-20-PARFWM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 680163aa-b425-4466-a420-e882564b490b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARFWM-14A (Bone Marrow Normal), aliquot TARGET-20-PARFWM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58430dbc-b9b4-43e8-8547-fde876bf8b0f

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1151G>A p.C384Y | Missense Mutation (SNP) | VAF 141/188 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs985412813, COSV50633156; called by muse, mutect2, varscan2
- LILRB1 | c.1675G>T p.G559W (on ENST00000427581; = p.G509W on NM_006669.6) | Missense Mutation (SNP) | VAF 3/82 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- NPM1 | c.868_872del p.W290Efs*7 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | called by pindel*, varscan2
